Somatic mutation profile of tumor specimen TARGET-50-PAJNRH-01A (aliquot TARGET-50-PAJNRH-01A-01D) from TARGET case TARGET-50-PAJNRH, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: female; Vital status: Alive; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 3.7 years (1,340 days).
Specimen TARGET-50-PAJNRH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0720c42-f77a-45f3-aa92-9858a915c4eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAJNRH-10A (Blood Derived Normal), aliquot TARGET-50-PAJNRH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b826696-2984-4856-9c92-f20dc53f7895

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1773C>A p.Y591* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | hotspot (GDC flag); catalogued as rs371369583, COSV60102562, COSV60102917; called by muse, mutect2, varscan2
- DICER1 | c.5125G>A p.D1709N | Missense Mutation (SNP) | VAF 56/115 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM144331, CM146274, CM160048, COSV58615449, COSV58627659; called by muse, mutect2, varscan2
- ABCA12 | c.2851G>A p.E951K (on ENST00000272895 / NM_173076.3; = p.E633K on NM_015657.3) | Missense Mutation (SNP) | VAF 243/548 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as rs1353723813, COSV55948964; called by muse, mutect2, varscan2
- DICER1 | c.5622C>G p.Y1874* | Nonsense Mutation (SNP) | VAF 403/779 reads (52%) | catalogued as COSV58616715, COSV58624114; called by muse, mutect2, varscan2
- GCOM1 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 105/235 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs150909622; called by muse, mutect2, varscan2
- DISP3 | c.4010G>A p.S1337N | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.86); called by muse, mutect2
- LRP1 | c.13044C>A p.L4348= | Silent (SNP) | VAF 36/58 reads (62%) | catalogued as COSV54518278, COSV54525648; called by muse, mutect2, varscan2
- MMP21 | c.27G>A p.P9= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs138060220; called by muse, varscan2
- RARG | c.993C>A p.L331= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV58433763; called by muse, mutect2, varscan2
